CCDI case PBBWJX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0fc4da70-56c0-4ab3-a82b-079b974ffde4

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,324 days).

Biospecimens (3 samples)
- Sample 0DJ8JL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJ8KK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJ8KQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
